Somatic mutation profile of tumor specimen TCGA-32-4209-01A (aliquot TCGA-32-4209-01A-01D-1353-08) from TCGA case TCGA-32-4209, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 40.8 years (14,903 days).
Specimen TCGA-32-4209-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a641951-43d9-428c-9b7d-892b318474e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-4209-10A (Blood Derived Normal), aliquot TCGA-32-4209-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cbef184-20d5-4055-815d-78c5e20e9e32

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 21, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADS | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 78/303 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs140853839, CM067636; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 92/331 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.042); catalogued as COSV58049398; called by muse, mutect2, varscan2
- B3GNT6 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs781973825; called by muse, mutect2
- BMP6 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1188835240, COSV51660528; called by muse, mutect2
- CEACAM5 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 113/375 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs138799075; called by mutect2, varscan2
- CFH | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 101/283 reads (36%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.55); catalogued as COSV66405731; called by muse, mutect2, varscan2
- CRTC2 | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as COSV57840992; called by muse, mutect2
- GEMIN5 | c.3436C>G p.H1146D | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV53557925; called by muse, mutect2, varscan2
- HEATR5B | c.1165A>G p.M389V | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.061); catalogued as COSV51848773; called by muse, mutect2, varscan2
- LEMD3 | c.2318A>G p.D773G | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.547); catalogued as rs750770845, COSV57648379; called by muse, mutect2, varscan2
- LILRB2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 140/476 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs145209585; called by muse, mutect2, varscan2
- LZTR1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769001939, COSV53145056; called by muse, mutect2, varscan2
- NKX3-2 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs868800217, COSV66711471; called by muse, mutect2
- NTSR1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100980624; called by muse, mutect2, varscan2
- NTSR1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs1161157004, COSV65138010; called by muse, mutect2
- POU2F1 | c.889C>G p.Q297E (on ENST00000541643 / NM_001365848.1; = p.Q320E on NM_002697.4) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54812624; called by muse, mutect2, varscan2
- SIRPG | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 78/328 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53805843; called by muse, mutect2, varscan2
- SWT1 | c.546G>C p.K182N | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV62252854; called by muse, mutect2
- TBCD | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as rs752953575, COSV62797542; called by muse, mutect2, varscan2
- TLL2 | c.1504G>A p.V502M | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs368837755; called by muse, mutect2, varscan2
- TMC7 | c.2164A>T p.R722W | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.872); catalogued as COSV58581464; called by muse, mutect2, varscan2
- ULK2 | c.1828A>C p.I610L | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as COSV64444155; called by muse, mutect2, varscan2
- ZNF492 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV71761661, COSV71761702, COSV71762292; called by muse, mutect2
- CNTNAP1 | c.3015G>A p.P1005= | Silent (SNP) | VAF 81/378 reads (21%) | catalogued as rs775278930, COSV52847839; called by muse, mutect2, varscan2
- MMP14 | c.717C>T p.H239= | Silent (SNP) | VAF 51/115 reads (44%) | catalogued as rs548260059, COSV100314011, COSV61287427; called by muse, mutect2, varscan2
- OR6C2 | c.837C>T p.V279= | Silent (SNP) | VAF 70/229 reads (31%) | catalogued as rs748191067, COSV59515526; called by muse, mutect2, varscan2
- STXBP5L | c.732A>G p.E244= | Silent (SNP) | VAF 91/310 reads (29%) | catalogued as COSV56499741; called by muse, mutect2, varscan2
